Somatic mutation profile of tumor specimen TCGA-3H-AB3M-01A (aliquot TCGA-3H-AB3M-01A-11D-A39R-32) from TCGA case TCGA-3H-AB3M, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 53.4 years (19,503 days).
Specimen TCGA-3H-AB3M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e5b0914-a6f9-43b4-b7af-1f5512fce7b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3H-AB3M-10A (Blood Derived Normal), aliquot TCGA-3H-AB3M-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f4d60e3-7b15-4b61-9cfe-1167fb3b1720

The open-access MAF lists 36 somatic variants for this specimen: 20 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 15, Frame Shift Del 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL28A1 | c.2887G>C p.D963H | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68082985; called by muse, mutect2, varscan2
- IFIT2 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs769134303, COSV51078061, COSV51080184; called by muse, mutect2, varscan2
- OR8H3 | c.70G>T p.V24F | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV100539197, COSV57912419; called by muse, mutect2, varscan2
- PHKA1 | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.359); catalogued as COSV100263059; called by muse, mutect2, varscan2
- POLR2H | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as rs1234674745; called by muse, mutect2, varscan2
- SERTAD2 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs771819559; called by muse, mutect2, varscan2
- TBC1D25 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs1007608725; called by muse, mutect2
- EZH2 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- HGSNAT | c.1244G>T p.C415F | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HOXB6 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- LONRF2 | c.2261_2265del p.N754Ifs*46 | Frame Shift Del (DEL) | VAF 56/155 reads (36%) | called by mutect2, pindel, varscan2
- OBSCN | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 117/300 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLPPR3 | c.1105A>G p.N369D (on ENST00000520876 / NM_001270366.2; = p.N397D on NM_024888.2) | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POLR2B | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PPP1R12A | c.1471G>C p.G491R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- PRR19 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 53/76 reads (70%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- RSRC2 | c.934A>G p.I312V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); called by muse, mutect2
- SPANXN1 | c.126G>C p.K42N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TNRC18 | c.1675C>G p.P559A | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.3); called by muse, mutect2
- VCL | c.2318_2352del p.N773Sfs*4 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel
- CDH22 | c.1254G>A p.A418= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs1253119042, COSV100952922; called by muse, mutect2, varscan2
- DNAH3 | c.10356G>T p.S3452= | Silent (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- FMNL3 | c.1677T>A p.I559= | Silent (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- HCN1 | c.2253G>T p.P751= | Silent (SNP) | VAF 45/183 reads (25%) | catalogued as COSV57496113; called by muse, mutect2, varscan2
- MAGED1 | c.90G>A p.L30= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs1557364033; called by muse, mutect2, varscan2
- MGAT5B | c.699C>T p.F233= | Silent (SNP) | VAF 40/268 reads (15%) | catalogued as COSV56929576; called by muse, mutect2, varscan2
- MUC5B | c.9300G>A p.P3100= | Silent (SNP) | VAF 89/134 reads (66%) | catalogued as rs754160190, COSV71590663; called by muse, mutect2, varscan2
- OR2AK2 | c.165C>G p.L55= | Silent (SNP) | VAF 57/136 reads (42%) | catalogued as COSV63549215; called by muse, mutect2, varscan2
- PLXNA3 | c.5055C>T p.A1685= | Silent (SNP) | VAF 112/334 reads (34%) | called by muse, mutect2, varscan2
- RELT | c.498C>T p.I166= | Silent (SNP) | VAF 103/285 reads (36%) | catalogued as rs137866810; called by muse, mutect2, varscan2
- RPN1 | c.15C>G p.A5= | Silent (SNP) | VAF 40/127 reads (31%) | catalogued as rs919717895; called by muse, mutect2, varscan2
- RSBN1L | c.924G>A p.L308= | Silent (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- STAG2 | c.811C>A p.R271= | Silent (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- TLN1 | c.2445C>T p.S815= | Silent (SNP) | VAF 34/97 reads (35%) | called by muse, mutect2, varscan2
- TOX3 | c.1333T>C p.L445= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs754864123; called by muse, mutect2, varscan2
- HLA-DRB9 | n.140G>C | RNA (SNP) | VAF 24/192 reads (13%) | called by muse, mutect2
